Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A7ET, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A7ET-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

[REDACTED]

....

Clinical Diagnosis & History:

Left groin mass, FNA positive HG pleomorphic sarcoma.

Specimens Submitted:

1: Left lower abdominal wall mass

DIAGNOSIS:

1. Soft tissue, lower abdominal wall, left, mass, excision:
- Undifferentiated pleomorphic sarcoma (Malignant Fibrous Histiocytoma), high grade.
- Tumor measures 6.4 cm in greatest dimension.
- Mitoses: greater than 10 /10 HPF.
- Necrosis is present (10% of tumor).
- Surgical resection margins are uninvolved; closest margin - Inferior margin (clearance of 0.2cm).

Note: Sections show spindle cell neoplasm with tumor cells showing marked cytological atypia and nuclear pleomorphism with moderate amount of eosinophilic cytoplasm. Numerous interspersed bizarre cells with vesicular nuclei and prominent nucleoli are seen. Atypical mitotic figures were identified. Morphological findings are consistent with high grade, undifferentiated pleomorphic sarcoma.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

- 1) The Specimen received fresh labelled "Lower abdominal wall mass" consist of an ellipse of skin with underlying mass. The entire specimen measures

** Continued on next page **

ICD O-3

Sarcoma, pleomorphic cell undifferentiated
(8802/3) (8805/3)

Code to highest 8805/3

Site C49.6
Site Trunk NOS C49.6

path
Abdominal wall, ext tissue C49.4

JN 9/26/13

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 2
17.5 x 10.6 x 5.8cm. The skin ellipse measures 15 x 7.7cm. The specimen is oriented by a short stitch marking the superior margin and long stitch marking the lateral margin. The specimen is inked as follows: Lateral - Orange; medial - red; Superior - Blue, inferior - green; deep/posterior - black. The specimen is opened along the long axis to reveal a mass measuring 6.4 x 5.3 x 4.9cm. The mass is serially sectioned to reveal a yellow tan homogenous cut surface with a cystic area measuring 3.8 x 2.5 x .3cm. The cyst was filled by hemorrhagic fluid. Only rare areas of hemorrhage and necrosis are seen in the solid part of the tumor. The tumor is located 3.2cm from the lateral margin; 6.5cm from the medial margin; 1.8cm from the superior margin; 0.3cm from the inferior margin and the distance from deep margin is 0.4cm. A part of the specimen is submitted for TPS and photographs are taken

Summary of sections

LM - Lateral margin perpendicular
MM - Medial margin perpendicular
SM - Superior margin perpendicular
IM - Inferior margin perpendicular
DM - deep margin perpendicular
T - Tumor
S - Skin

Summary of Sections:

Part 1: Left lower abdominal wall mass

Block	Sect.	Site	PCs
1	DM	2	
1	IM	2	
1	LM	2	
1	MM	2	
1	S	1	
1	SM	2	
4	T	8	

** End of Report **

Source: NCI Genomic Data Commons file 35ed94b1-383f-4296-ae8a-41f8ed3f8996 (TCGA-DX-A7ET.7E70B9E4-9C76-47DD-A770-3446179E43A9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).